CPTAC case C3L-07037 — Pancreas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/19024c23-0e65-484b-9735-691d616f304d

Demographics
Sex at birth: female; Race: white; Year of birth: 1963.

Other clinical attributes
- Weight: 81.2 kg; Height: 155 cm; BMI: 33.8.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (1 sample)
- Sample C3L-07037-01: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 50 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
